CCDI case PBCEJE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/14a8a106-2256-4f02-924a-ec1cb102899b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Aggressive fibromatosis: ICD-O-3 morphology code: 8821/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 1.6 years (592 days).

Biospecimens (1 sample)
- Sample 0DPX3X: Tissue type: Tumor; Specimen type: Solid Tissue.
